Gene-level copy-number profile of tumor specimen ALCH-B3E3-TTP1-A from ALCHEMIST case ALCH-B3E3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.2 years (22,725 days).
Specimen ALCH-B3E3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8f5207eb-f6cf-4bb8-9f03-678cbfea1c6e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3E3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/2134f661-55dc-4fba-b810-9dfe3f13696f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 98; copy number 1: 11,837; copy number 2: 44,943; copy number 3: 1,888; copy number 4: 115; copy number 5: 7; copy number 6: 5; copy number 7: 2; copy number 8: 2; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,425,257–11,425,821, 1 gene: MTCYBP45.
- chr2:44,065,894–44,066,154, 1 gene: AC019129.1.
- chr3:57,941,818–57,942,304, 1 gene: PPIAP16.
- chr3:121,356,991–121,357,940, 1 gene (within-gene range 0–2): AC079841.1.
- chr4:164,597,719–164,620,837, 2 genes: AC074198.1, RNU6-284P.
- chr5:179,678,560–179,681,034, 1 gene (within-gene range 0–2): CBY3.
- chr5:179,679,032–179,694,768, 1 gene (within-gene range 0–2): HMGB3P22.
- chr6:85,777,639–85,869,464, 2 genes: Y_RNA, AL450338.1.
- chr6:89,886,156–89,921,760, 3 genes (within-gene range 0–2): AL353692.1, GJA10, Y_RNA.
- chr7:55,731,100–55,773,288, 6 genes: Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1.
- chr7:93,099,513–93,118,023, 1 gene: SAMD9.
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.
- chr8:20,246,165–20,303,963, 3 genes: LZTS1, LZTS1-AS1, RNA5SP257.
- chr8:30,678,066–30,767,006, 3 genes: GSR, UBXN8, HIKESHIP3.
- chr8:33,641,581–33,641,939, 1 gene (within-gene range 0–2): BUD31P1.
- chr9:841,690–969,090, 1 gene: DMRT1.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr9:93,951,627–93,959,140, 2 genes: BARX1, BARX1-DT.
- chr9:124,853,417–124,857,890, 1 gene (within-gene range 0–2): WDR38.
- chr9:131,096,476–131,123,152, 1 gene: AIF1L.
- chr10:118,643,760–118,644,198, 1 gene: TOMM22P5.
- chr12:111,304,142–111,451,623, 6 genes (within-gene range 0–2): MIR6760, RNA5SP373, PHETA1, LINC02356, HSPA8P14, SH2B3.
- chr12:118,063,593–118,136,026, 2 genes (within-gene range 0–2): VSIG10, AC131238.1.
- chr14:103,847,721–103,880,381, 3 genes: LINC00637, AL132712.1, AL132712.2.
- chr15:85,744,109–85,794,925, 6 genes (within-gene range 0–4): AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr16:29,662,979–29,698,699, 2 genes: SPN, QPRT.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr16:75,192,465–75,226,338, 3 genes (within-gene range 0–1): AC009078.1, CTRB2, CTRB1.
- chr17:2,748,078–2,748,182, 2 genes (within-gene range 0–1): MIR1253, hsa-mir-1253.
- chr17:58,631,641–58,631,836, 1 gene (within-gene range 0–2): U3.
- chr17:58,666,537–58,679,690, 4 genes (within-gene range 0–2): RNU1-108P, AC011195.1, RNU1-52P, RNVU1-34.
- chr22:17,787,649–18,177,397, 16 genes (within-gene range 0–1): MICAL3, AC016026.1, AC016026.2, MIR648, AC016027.3, AC016027.2, RHEBP3, LINC01634, AC016027.1, PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,418,420–1,422,691, 2 genes, copy number 7–16: ANKRD65, AL391244.1.
- chr5:177,801,204–177,803,344, 1 gene, copy number 7: AC140125.1.
- chr9:60,914,407–61,453,030, 12 genes, copy number 5–6: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr20:64,290,187–64,313,132, 2 genes, copy number 8: CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 9,007. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
